Gene-level copy-number profile of tumor specimen TCGA-37-3792-01A from TCGA case TCGA-37-3792, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 69.8 years (25,502 days).
Specimen TCGA-37-3792-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.42f4426e-239d-4ef6-b680-09338ba60cd3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-37-3792-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/301f01ea-5521-4825-a721-e9d2015db3c1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 30; copy number 1: 3,237; copy number 2: 23,213; copy number 3: 11,212; copy number 4: 19,209; copy number 5: 1,273; copy number 6: 905; copy number 7: 409; copy number 8: 326.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-37-3792-01A-01D-1969-01): tumor purity 0.4, ploidy 2.6, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,913 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:56,994,778–66,374,579, 138 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr1:75,127,830–79,282,124, 69 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr3:147,590,996–198,222,513, 908 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–38,945,596, 605 genes, copy number 5–8 (broad region; genes not listed).
- chr5:40,066,651–45,895,970, 93 genes, copy number 5 (broad region; genes not listed).
- chr9:14,475–43,045,120, 776 genes, copy number 6 (broad region; genes not listed).
- chr12:66,767–9,010,760, 318 genes, copy number 5–8 (broad region; genes not listed).
- chr12:20,695,332–21,176,895, 6 genes, copy number 7 (within-gene range 3–7): SLCO1C1, SLCO1B3, SLCO1B3-SLCO1B7, AC011604.1, SLCO1B7, AC022335.1.

Autosomal genes at a single copy (total copy number 1): 1,457. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
